Gene-level copy-number profile of tumor specimen TCGA-DU-7015-01A from TCGA case TCGA-DU-7015, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 41.2 years (15,041 days).
Specimen TCGA-DU-7015-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.30e636c8-5c65-4d07-9753-317bffbda0c0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DU-7015-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/db99f8af-fde6-4f1b-bb17-c287e0e16064

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,787; copy number 2: 50,769; copy number 3: 4,342; copy number 4: 11; copy number 5: 871; copy number 6: 34.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DU-7015-01A-11D-2023-01): tumor purity 0.32, ploidy 4.22, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 905 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:130,645,225–131,948,953, 30 genes, copy number 6: AC234644.1, TSGA13, AC234644.2, KLF14, AC016831.5, AC016831.6, AC016831.2, H4P1, AC016831.3, LINC00513, MIR29A, AC016831.1, MIR29B1, AC016831.4, AC058791.1, LINC-PINT, RNU6-1010P, MKLN1, AC009362.1, MKLN1-AS, AC008264.2, PODXL, AC008264.1, EEF1B2P6, AC093106.1, AC093106.2, NDUFB9P2, CAPZA1P4, AC009518.2, AC009518.1.
- chr7:137,874,979–138,002,086, 2 genes, copy number 6: CREB3L2, CREB3L2-AS1.
- chr7:138,022,458–138,047,897, 2 genes, copy number 6: AC009263.1, AC024082.1.
- chr7:138,831,381–139,109,720, 5 genes, copy number 5 (within-gene range 3–5): KIAA1549, RNU6-1272P, ZC3HAV1L, ZC3HAV1, AC018644.1.
- chr7:142,875,836–159,233,377, 347 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr8:112,222,928–145,066,685, 519 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,366. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
